Surgical pathology report (de-identified scan), TCGA case TCGA-X4-A8KQ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Institute for Medical Research, specimen TCGA-X4-A8KQ-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Adenocarcinoma NOS 8140/B
Site: Prostate NOS C61.9
JW 4/14/14

---- SURGICAL PATHOLOGY ----

MEDICAL RECORD	SURGICAL PATHOLOGY
PATHOLOGY REPORT	
Laboratory:	Accession No.
Submitted by:	Date obtained:
Specimen (Received)	
1. PROSTATE BILATERAL LYMPH NODES, RT IS CLIPPED	
2. PERI-PROSTETIC FAT-RESEARCH LAB	
3. SQ FAT-RESEARCH LAB	
BRIEF CLINICAL HISTORY:	
PREOPERATIVE DIAGNOSIS:	
PROSTATE CANCER	
OPERATIVE FINDINGS:	
POSTOPERATIVE DIAGNOSIS:	
PROSTATE CANCER	
Surgeon/physician:	
PATHOLOGY REPORT	
Laboratory:	Accession No.
Pathology Resident:	

Gross description:

Specimen 1, "prostate and bilateral lymph nodes." Received fresh for research and later placed in formalin is a 40.7 gram, 5.5 (right-left) x 4.5 (superior-inferior) x 2.8 (anterior-posterior) cm prostate with bilateral seminal vesicles (right-4 x 1.7 x 0.4 cm and left-3.8 x 3 x 0.7 cm). The specimen is inked as follows: apex-green, bladder neck-yellow, right prostate-black, and left prostate-blue. The specimen is serially sectioned from apex to bladder neck and demonstrate periurethral nodularities up to 1 x 0.8 cm in greatest dimension. There is also 2 x 2 x 1.5 cm from, pale, ill-defined area in the parenchyma. Approximately 25-30% of the bowel parenchyma bilaterally were submitted for research. Serial sectioning of the bilateral seminal vesicle demonstrate unremarkable cut surface.

Also received in the container are bilateral unoriented lymph nodes with attached adipose tissue. One lymph node has a clip on it measuring 3.5 x 1.8 x 1 cm and the other lymph node is 4.2 x 2.8 x 1 cm. All lymph nodes are bisected and demonstrate tan-white, firm cut surface. The specimen is submitted in toto as follows:

- Block 1 - right apex
- Block 2 - left apex
- Block 3 - right bladder neck
- Block 4 - left bladder neck
- Block 5-18 - right prostate
- Block 19-34- left prostate
- Block 35- representative sections of right and left seminal vesicles
- Block 36-37 - two lymph nodes with no clip, bisected (toto)
- Block 38 - lymph node with clip, bisected, submitted in toto

Microscopic exam:

Atypical glands are focally present in a crowded, infiltrative

[page 2 of 2]
pattern, and they comprise cells with enlarged nuclei and more abundant cytoplasm than usual.

Diagnosis:

NO. 1: 40.7 GM PROSTATE: ADENOCARCINOMA PRESENT CONFINED TO RIGHT SIDE

NO. 2: GLEASON SCORE: 4+3

NO. 3: PERCENT OF GLAND WITH TUMOR: 16%

NO. 4: EXTRA-PROSTATIC TISSUES: POSITIVE FOR TUMOR ON RIGHT SIDE

NO. 5: APICAL SURGICAL MARGINS: NEGATIVE FOR TUMOR

NO. 6: PERIPHERAL SURGICAL MARGINS: POSITIVE FOR TUMOR IN 2 FOCI ON RIGHT SIDE

NO. 7: SEMINAL VESICLES: POSITIVE FOR TUMOR ON RIGHT SIDE AT JUNCTION WITH PROSTATE

NO. 8: BLADDER NECK MARGINS: NO TUMOR SEEN.

NO. 10: RIGHT LYMPH NODES: NO TUMOR SEEN (0/1 NODES)

NO. 11: LEFT LYMPH NODES: NO TUMOR SEEN (0/2 NODES)

pSTAGE: T3BNOMX

Signed

(End of report)

IIFAA Discrepancy		☒

Source: NCI Genomic Data Commons file b4a33afe-78ac-490a-867a-36b61a3b7775 (TCGA-X4-A8KQ.978B4E1F-FDA4-41FA-8341-ED6E851168A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).